Somatic mutation profile of tumor specimen MMRF_1856_1_BM_CD138pos (aliquot MMRF_1856_1_BM_CD138pos_T1_KBS5U_L05778) from MMRF case MMRF_1856, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.0 years (20,072 days).
Specimen MMRF_1856_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa51cdcd-e0b8-4929-bb65-2cccbd556987.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1856_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1856_1_PB_Whole_C3_KBS5U_L05804; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5446890d-4ec2-41f4-9fda-53c86c270c55

The open-access MAF lists 81 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 24, Silent 7, RNA 7, 5'UTR 3, 3'Flank 3, Intron 3, Frame Shift Del 2, Nonsense Mutation 2, 5'Flank 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 29/67 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1305925156; called by muse, mutect2
- ADAMTS5 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.892); catalogued as COSV99538209; called by muse, mutect2, varscan2
- C3orf20 | c.1388G>A p.W463* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as rs151168843, COSV53790402; called by muse, mutect2, varscan2
- CCDC120 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782709167; called by muse, mutect2
- CCDC180 | c.4600+3A>T | Splice Region (SNP) | VAF 6/31 reads (19%) | catalogued as rs376224397; called by muse, mutect2, varscan2
- EXTL3 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs373430705; called by muse, mutect2, varscan2
- GRIN2B | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.042); catalogued as COSV101663184, COSV74205547; called by muse, mutect2, varscan2
- IDO1 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753896549; called by muse, mutect2, varscan2
- IGKV4-1 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs375619633; called by muse, varscan2
- KMT2D | c.12923C>T p.T4308I | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.24); catalogued as rs769751385; called by muse, mutect2, varscan2
- MAGED1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs782818810, COSV58515197; called by muse, mutect2, varscan2
- MSLN | c.778A>T p.I260F | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.305); catalogued as rs1402225897; called by muse, mutect2, varscan2
- PCDH15 | c.4325C>T p.P1442L | Missense Mutation (SNP) | VAF 70/131 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as rs1397371546, COSV100222255; called by muse, mutect2, varscan2
- ROBO2 | c.843A>C p.K281N | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.867); catalogued as COSV59928041; called by muse, mutect2, varscan2
- SYNE1 | c.582G>T p.K194N (on ENST00000367255 / NM_182961.4; = p.K201N on NM_033071.3) | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV54913933; called by muse, mutect2, varscan2
- TPO | c.1403del p.G468Vfs*34 | Frame Shift Del (DEL) | VAF 31/193 reads (16%) | catalogued as COSV100220493, COSV100221474; called by mutect2, pindel, varscan2
- BMS1 | c.145T>A p.S49T | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- CDH13 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV2-70D | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT tolerated (0.48); PolyPhen benign (0.194); called by muse, varscan2
- IGHV2-70D | c.214A>T p.I72F | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, varscan2
- IGHV2-70D | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- IGLV3-1 | c.212_215dup p.P73Afs*7 | Frame Shift Ins (INS) | VAF 35/107 reads (33%) | called by mutect2, pindel, varscan2
- LRP1B | c.12239A>G p.Y4080C | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- NOL4 | c.806A>G p.E269G | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- OR5M1 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ROBO4 | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SHC4 | c.586-2A>T p.X196_splice | Splice Site (SNP) | VAF 38/126 reads (30%) | called by muse, mutect2, varscan2
- SLC26A8 | c.1388T>G p.L463R | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- SLC5A12 | c.30T>G p.D10E | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPOCK3 | c.647G>A p.W216* | Nonsense Mutation (SNP) | VAF 77/155 reads (50%) | called by muse, mutect2, varscan2
- TRIM41 | c.828del p.H277Tfs*5 | Frame Shift Del (DEL) | VAF 36/85 reads (42%) | called by mutect2, pindel, varscan2
- A1BG | c.1446G>A p.S482= | Silent (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.102A>C p.T34= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs559222113; called by muse, varscan2
- IGHV2-70D | c.111C>T p.L37= | Silent (SNP) | VAF 48/51 reads (94%) | called by muse, varscan2
- KIF13B | c.4935G>T p.P1645= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- KRTAP13-2 | c.225C>T p.P75= | Silent (SNP) | VAF 39/116 reads (34%) | called by muse, mutect2, varscan2
- OBSCN | c.357C>T p.I119= | Silent (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- ZNF35 | c.1026A>T p.T342= | Silent (SNP) | VAF 83/274 reads (30%) | catalogued as COSV56076449; called by muse, mutect2, varscan2
- AC064805.2 | n.2814C>T | RNA (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- ADHFE1 | c.*322A>C | 3'UTR (SNP) | VAF 15/93 reads (16%) | catalogued as COSV52559670; called by muse, mutect2, varscan2
- AL583810.2 | n.1540C>T | RNA (SNP) | VAF 64/124 reads (52%) | catalogued as rs1192739721; called by muse, mutect2, varscan2
- ARHGAP5 | c.*2676T>C | 3'UTR (SNP) | VAF 47/93 reads (51%) | catalogued as rs1173105512; called by muse, mutect2
- ARID2 | c.*1743dup | 3'UTR (INS) | VAF 30/82 reads (37%) | catalogued as rs933450140; called by mutect2, varscan2
- ATP11C | c.*2247C>A | 3'UTR (SNP) | VAF 25/25 reads (100%) | called by muse, mutect2, varscan2
- BRAF | chr7:140734382 T>A | 3'Flank (SNP) | VAF 15/30 reads (50%) | catalogued as rs140083479; called by muse, mutect2, varscan2
- BTLA | c.*1280_*1284del | 3'UTR (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- C11orf87 | c.*4251A>G | 3'UTR (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- CA5BP1 | n.406G>A | RNA (SNP) | VAF 71/71 reads (100%) | called by muse, mutect2, varscan2
- CA5BP1 | n.658A>G | RNA (SNP) | VAF 44/44 reads (100%) | catalogued as rs749259254; called by muse, mutect2, varscan2
- CAMK4 | c.*2320T>C | 3'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- CSRNP3 | c.*1511del | 3'UTR (DEL) | VAF 31/86 reads (36%) | called by mutect2, pindel, varscan2
- CSRNP3 | c.*1657A>G | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- DHRS2 | c.*71T>A | 3'UTR (SNP) | VAF 27/61 reads (44%) | catalogued as rs955531112; called by muse, mutect2, varscan2
- DOK1 | c.-328T>C | 5'UTR (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2
- DTWD2 | c.*1799G>A | 3'UTR (SNP) | VAF 2/8 reads (25%) | catalogued as rs1283855209; called by muse, mutect2
- FLT4 | c.2167+20C>T | Intron (SNP) | VAF 111/219 reads (51%) | called by muse, mutect2, varscan2
- GALNT3 | c.*901A>G | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- GCNT1 | c.*499T>A | 3'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- GCNT1 | c.*653T>C | 3'UTR (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- GNA14 | c.-284G>T | 5'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- HSPA12A | c.*559C>G | 3'UTR (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- LDHA | chr11:18408060 A>G | 3'Flank (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- LINC01148 | n.1460C>A | RNA (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- LTA | c.*412G>A | 3'UTR (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- MASP2 | c.*17C>T | 3'UTR (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851327 T>G | 5'Flank (SNP) | VAF 59/118 reads (50%) | catalogued as rs1425892142; called by muse, mutect2, varscan2
- PTGDR2 | c.*166G>A | 3'UTR (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- RAD18 | c.*1627C>T | 3'UTR (SNP) | VAF 62/134 reads (46%) | catalogued as rs1002421146; called by muse, mutect2, varscan2
- RAPGEF6 | c.3746-2575T>C | Intron (SNP) | VAF 53/164 reads (32%) | called by muse, mutect2, varscan2
- RBPJ | c.*2428T>A | 3'UTR (SNP) | VAF 38/77 reads (49%) | called by muse, mutect2, varscan2
- RC3H1 | c.*4637T>G | 3'UTR (SNP) | VAF 52/101 reads (51%) | called by muse, mutect2, varscan2
- RERG | c.*1266T>A | 3'UTR (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- RPL23 | c.*16-463C>T | Intron (SNP) | VAF 3/10 reads (30%) | catalogued as rs985731152; called by muse, mutect2
- RSL1D1 | chr16:11851550 ins AG | 5'Flank (INS) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- SEMA3C | c.-25G>T | 5'UTR (SNP) | VAF 113/233 reads (48%) | called by muse, mutect2, varscan2
- SNORD64 | n.29C>G | RNA (SNP) | VAF 66/137 reads (48%) | called by muse, mutect2, varscan2
- SORBS3 | c.*787T>G | 3'UTR (SNP) | VAF 59/117 reads (50%) | called by muse, mutect2, varscan2
- VPS8 | chr3:185052612 C>A | 3'Flank (SNP) | VAF 9/29 reads (31%) | called by mutect2, varscan2
- ZNF252P | n.1014A>C | RNA (SNP) | VAF 46/82 reads (56%) | called by muse, mutect2, varscan2
- ZNRF3 | c.*3515G>A | 3'UTR (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
